Somatic mutation profile of tumor specimen MP2PRT-PARACA-TMP1-A (aliquot MP2PRT-PARACA-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARACA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (972 days).
Specimen MP2PRT-PARACA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c21c6c4-475e-40db-b2ea-8c7dc406448b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARACA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARACA-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b196552-5be9-45d3-ac06-cf6c2291f3a1

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIP2A | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 264/569 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV59488609; called by muse, mutect2, varscan2
- MYO1F | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 246/639 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs201138222, COSV57796026; called by muse, mutect2, varscan2
- PBX1 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV63348769; called by muse, mutect2
- APOB | c.9071A>G p.H3024R | Missense Mutation (SNP) | VAF 31/512 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2
- KLHL7 | c.1085G>T p.W362L (on ENST00000339077 / NM_001031710.3; = p.W314L on NM_018846.5) | Missense Mutation (SNP) | VAF 20/393 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- PFKL | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- RNF133 | c.471C>G p.N157K | Missense Mutation (SNP) | VAF 49/461 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A11 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SPI1 | c.198del p.E67Rfs*119 | Frame Shift Del (DEL) | VAF 222/552 reads (40%) | called by mutect2, pindel, varscan2
- TMEM101 | c.157_160dup p.Y54Sfs*15 | Frame Shift Ins (INS) | VAF 39/349 reads (11%) | called by mutect2, pindel, varscan2
- ENO4 | c.675T>G p.P225= (on ENST00000622726; = p.P224= on NM_001242699.2) | Silent (SNP) | VAF 183/367 reads (50%) | called by muse, mutect2, varscan2
- FREM1 | c.4068C>T p.T1356= | Silent (SNP) | VAF 168/414 reads (41%) | catalogued as rs1316144391, COSV66524946; called by muse, varscan2
- ITIH4 | c.342C>T p.S114= | Silent (SNP) | VAF 181/416 reads (44%) | catalogued as rs772784447, COSV56576651; called by muse, mutect2, varscan2
- PRORY | n.202G>A | RNA (SNP) | VAF 183/205 reads (89%) | called by muse, mutect2, varscan2
